Somatic mutation profile of tumor specimen TCGA-MQ-A6BQ-01A (aliquot TCGA-MQ-A6BQ-01A-11D-A34C-32) from TCGA case TCGA-MQ-A6BQ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 58.1 years (21,236 days).
Specimen TCGA-MQ-A6BQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8719a033-327a-4e4b-947e-fb6e995a4075.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A6BQ-10A (Blood Derived Normal), aliquot TCGA-MQ-A6BQ-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82628585-3868-4b5c-b049-e2266d195af0

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Frame Shift Del 2, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51888206; called by muse, mutect2, varscan2
- ARAF | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs773486607, COSV51693161; called by muse, mutect2, varscan2
- BAP1 | c.214_238del p.I72Cfs*7 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV56231873; called by mutect2, pindel
- CACNA2D2 | c.3008A>C p.E1003A (on ENST00000479441 / NM_001174051.3; = p.E996A on NM_006030.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.164); catalogued as COSV56564628; called by muse, mutect2
- COL4A2 | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV64629330; called by muse, mutect2, varscan2
- DST | c.3451A>T p.N1151Y (on ENST00000361203 / NM_001374722.1; = p.N825Y on NM_001723.6) | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV55020147; called by muse, mutect2, varscan2
- FAM111B | c.1614del p.S539Pfs*5 | Frame Shift Del (DEL) | VAF 54/207 reads (26%) | catalogued as COSV59112233; called by mutect2, pindel, varscan2
- FGFR1 | c.426T>A p.D142E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV58336254; called by muse, mutect2, varscan2
- HAUS4 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as rs1200730784, COSV52827551; called by muse, mutect2, varscan2
- MYC | c.1073C>G p.T358R (on ENST00000377970; = p.T373R on NM_002467.6) | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52374031; called by muse, mutect2, varscan2
- PDIA4 | c.1775C>T p.P592L (on ENST00000286091 / NM_001371244.1; = p.P591L on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV53725122; called by muse, mutect2, varscan2
- PLA2R1 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368913848; called by muse, mutect2, varscan2
- PRR11 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 56/226 reads (25%) | catalogued as COSV51877137; called by muse, mutect2, varscan2
- SLC6A2 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.506); catalogued as rs375910266; called by muse, mutect2, varscan2
- SPHKAP | c.4180A>G p.T1394A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV60882596; called by muse, mutect2, varscan2
- SRGAP3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64534367; called by muse, mutect2, varscan2
- TBL1Y | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as rs1246574814, COSV60733257; called by mutect2, varscan2
- VEZT | c.2255T>G p.F752C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54140356; called by muse, mutect2, varscan2
- YTHDC2 | c.4055T>C p.I1352T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as rs1476684031, COSV50742586; called by muse, mutect2, varscan2
- FOCAD | c.2792G>C p.S931T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD5 | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MZF1 | c.833_834dup p.V279Tfs*34 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- PON1 | c.781-10_781-2del p.X261_splice | Splice Site (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- SCFD2 | c.1551A>G p.Q517= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV66372824; called by muse, mutect2, varscan2
- VWA2 | c.739C>T p.L247= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs943814358, COSV53907445; called by muse, mutect2, varscan2
